Somatic mutation profile of tumor specimen TCGA-EJ-5497-01A (aliquot TCGA-EJ-5497-01A-02D-1576-08) from TCGA case TCGA-EJ-5497, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 48.0 years (17,523 days).
Specimen TCGA-EJ-5497-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 989e68f8-a3a0-43be-8a46-7907f26470bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5497-10A (Blood Derived Normal), aliquot TCGA-EJ-5497-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aebaee38-4b14-48a8-8efe-cc6469992d2e

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOC | c.617C>A p.T206K | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52023897; called by muse, mutect2
- BAHCC1 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs914389237, COSV57023955; called by muse, mutect2, varscan2
- CERS3 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV52565917; called by muse, mutect2, varscan2
- CPNE6 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV53742942; called by mutect2, varscan2
- EYA2 | c.1022A>C p.N341T | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57939834; called by muse, varscan2
- LCE1F | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV57668863; called by muse, mutect2, varscan2
- LCE1F | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV57668882; called by muse, mutect2, varscan2
- LMO7 | c.746A>G p.D249G (on ENST00000357063; = p.D264G on NM_005358.5) | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV58531685; called by muse, mutect2
- LPAR1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs780532844, COSV62687475, COSV62690705; called by muse, mutect2, varscan2
- MED17 | c.1074del p.T359Lfs*13 | Frame Shift Del (DEL) | VAF 39/245 reads (16%) | catalogued as rs1420801548; called by mutect2, pindel, varscan2
- RSPH4A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs768193419, COSV57633953; called by muse, mutect2, varscan2
- SIPA1L1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1297221334, COSV62168316; called by muse, mutect2
- SYNE1 | c.16513A>G p.T5505A (on ENST00000367255 / NM_182961.4; = p.T5434A on NM_033071.3) | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54928137; called by muse, mutect2
- CSMD3 | c.9860del p.L3287Yfs*37 (on ENST00000297405 / NM_001363185.1; = p.L3118Yfs*37 on NM_052900.3) | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- FASTKD2 | c.1008del p.E336Dfs*2 | Frame Shift Del (DEL) | VAF 35/205 reads (17%) | called by mutect2, pindel, varscan2
- NCAPD3 | c.2346G>A p.K782= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV73257987; called by muse, mutect2, varscan2
- PCDHA2 | c.2004G>A p.S668= | Silent (SNP) | VAF 12/169 reads (7%) | catalogued as rs369554786; called by muse, mutect2
- PHF20 | c.969A>G p.L323= | Silent (SNP) | VAF 7/164 reads (4%) | catalogued as COSV59184931; called by muse, mutect2
- SPATA31A3 | c.504C>A p.T168= | Silent (SNP) | VAF 28/717 reads (4%) | called by muse, mutect2
